CPTAC case C3L-06940 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7dc0de32-017f-482a-92bc-682836e728b7

Demographics
Sex at birth: male; Race: white; Year of birth: 1951; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 69.3 years (25,321 days); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 266 days; Days to last follow up: 266 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 13 cm; Lymph node involvement: Positive; Lymph nodes positive: 8; Lymph nodes tested: 12.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 49 days; Days to treatment end: 59 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 49 days; Days to treatment end: 59 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 96 days; Days to treatment end: 105 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 96 days; Days to treatment end: 105 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 161 days; Days to treatment end: 166 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 161 days; Days to treatment end: 166 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 190 days; Days to treatment end: 195 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 190 days; Days to treatment end: 195 days; Treatment outcome: Stable Disease.

Follow-up (1 entry)
- Days to follow up: 266 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Cigarettes per day: 10; Tobacco smoking onset year: 1974; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06940-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 8 days; Initial weight: 570 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide CPT039451 0001: Section location: body and antrum; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-06940-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 8 days; Initial weight: 640 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-06940-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 8 days; Method of sample procurement: Blood Draw.
